Somatic mutation profile of tumor specimen TCGA-62-8398-01A (aliquot TCGA-62-8398-01A-11D-2323-08) from TCGA case TCGA-62-8398, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 55.3 years (20,197 days).
Specimen TCGA-62-8398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0723267-c2a2-4d20-8398-c50828b6f46d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-8398-10A (Blood Derived Normal), aliquot TCGA-62-8398-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2b7b02a-9b6b-43cc-a430-f18b565e8a20

The open-access MAF lists 87 somatic variants for this specimen: 67 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 17, Nonsense Mutation 5, Frame Shift Del 2, In Frame Del 1, RNA 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.6612T>G p.F2204L | Missense Mutation (SNP) | VAF 67/92 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99794470; called by muse, mutect2, varscan2
- ARHGAP35 | c.2531T>C p.F844S | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as rs765848742, COSV101350726; called by muse, mutect2, varscan2
- ARHGEF40 | c.3413G>A p.R1138Q | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs766903112, COSV100070044; called by muse, mutect2, varscan2
- ATM | c.8875G>A p.D2959N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV53739395, COSV53745096, COSV99587492; called by muse, mutect2, varscan2
- BIRC7 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1364690930, COSV99416465; called by muse, mutect2, varscan2
- C9orf135 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.755); catalogued as COSV101019720, COSV65876551; called by muse, mutect2, varscan2
- CCDC144A | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as COSV100138383, COSV100138405, COSV60698221; called by muse, mutect2, varscan2
- CDH10 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as rs544303560, COSV52580956; called by muse, mutect2, varscan2
- CNTNAP5 | c.2962C>T p.P988S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV101443092; called by muse, mutect2, varscan2
- COL24A1 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100992925; called by muse, mutect2, varscan2
- CSF2RA | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 112/192 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100817496; called by muse, varscan2
- DCUN1D3 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1173145534, COSV100176728, COSV60952433; called by muse, mutect2, varscan2
- DNAH3 | c.12295C>A p.P4099T | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV99765187; called by muse, mutect2, varscan2
- DNAH5 | c.13790A>G p.Y4597C | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99445534; called by muse, mutect2, varscan2
- DNER | c.2122C>A p.P708T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100518427; called by muse, mutect2, varscan2
- DUS3L | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100287902; called by muse, mutect2, varscan2
- FAT3 | c.3610C>G p.L1204V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs754830139, COSV99962410; called by muse, varscan2
- GLOD4 | c.530A>C p.K177T (on ENST00000301328 / NM_001366247.1; = p.K162T on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV100022421; called by muse, mutect2, varscan2
- GLYATL1 | c.868C>T p.H290Y (on ENST00000317391 / NM_001354699.1; = p.H321Y on NM_080661.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV100265161; called by muse, mutect2, varscan2
- GPR85 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99775073; called by muse, mutect2, varscan2
- GRIN2B | c.1993G>T p.G665C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101662927; called by muse, mutect2, varscan2
- GRM5 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100550384; called by muse, mutect2, varscan2
- IFI16 | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99857083; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 46/428 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs1280828630; called by muse, mutect2, varscan2
- ITGA7 | c.866A>G p.D289G (on ENST00000555728; = p.D245G on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1366739729, COSV99144365; called by muse, mutect2, varscan2
- KCNU1 | c.2158G>T p.V720L | Missense Mutation (SNP) | VAF 73/343 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.184); catalogued as COSV101298960; called by muse, mutect2, varscan2
- KEAP1 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407371; called by muse, mutect2, varscan2
- KIAA1328 | c.1440T>G p.D480E | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99693355; called by muse, mutect2, varscan2
- LAMA1 | c.2409C>A p.S803R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101055152; called by muse, mutect2, varscan2
- LYPD6B | c.61G>C p.A21P (on ENST00000409029 / NM_001317004.1; = p.A45P on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.306); catalogued as COSV54518152, COSV99700054; called by muse, mutect2, varscan2
- MED12L | c.3979T>G p.W1327G | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV99851684; called by muse, mutect2, varscan2
- METTL17 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100068470; called by muse, mutect2, varscan2
- MGAT5 | c.1119G>T p.M373I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV56096168, COSV99924124; called by muse, mutect2, varscan2
- MKRN3 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1355045325, COSV58810017; called by muse, mutect2, varscan2
- MROH9 | c.1552A>T p.R518* | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | catalogued as COSV100882695; called by muse, mutect2, varscan2
- NTM | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs951593215, COSV66177489; called by muse, mutect2, varscan2
- NXF1 | c.1751G>T p.W584L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99585778; called by muse, mutect2, varscan2
- OR2T11 | c.243C>A p.D81E | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1295505498, COSV100424709; called by muse, mutect2, varscan2
- PDILT | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 101/310 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56706189; called by muse, mutect2, varscan2
- PIK3C2G | c.1895G>T p.G632V (on ENST00000676171; = p.G591V on NM_004570.5) | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs757571836, COSV99849769; called by muse, mutect2, varscan2
- PKP2 | c.1937G>C p.G646A | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99297261; called by muse, mutect2, varscan2
- PRB3 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 426/786 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV99685506; called by muse, varscan2
- PRDM9 | c.2562C>A p.H854Q | Missense Mutation (SNP) | VAF 89/184 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99689839; called by muse, mutect2, varscan2
- PTPN13 | c.1549A>G p.T517A | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV100364100; called by muse, mutect2
- PTPRH | c.2522C>A p.A841D | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99670724; called by muse, mutect2, varscan2
- RAVER1 | c.1768A>T p.M590L (on ENST00000615032; = p.Y716F on NM_133452.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99532360; called by muse, mutect2, varscan2
- RFX6 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100263325; called by muse, mutect2, varscan2
- SETX | c.4255T>G p.S1419A | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as COSV99808889; called by muse, mutect2, varscan2
- SEZ6L | c.1426A>G p.S476G | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99961429; called by muse, mutect2, varscan2
- SLC17A6 | c.1145C>G p.T382R | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54138033, COSV99580837; called by muse, mutect2, varscan2
- SLC9A5 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV100237091; called by muse, mutect2, varscan2
- SLCO1C1 | c.406T>A p.Y136N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99858564; called by muse, mutect2, varscan2
- SMYD1 | c.190C>G p.R64G | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV101352396, COSV101352401; called by muse, mutect2, varscan2
- SORL1 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV99492944; called by muse, mutect2, varscan2
- TMEM132D | c.3212A>T p.D1071V | Missense Mutation (SNP) | VAF 122/194 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV101242555; called by muse, mutect2, varscan2
- USP47 | c.2195T>A p.I732K (on ENST00000399455 / NM_001372095.1; = p.I644K on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100359203; called by muse, mutect2, varscan2
- YIPF7 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs754855720, COSV100274344; called by muse, mutect2, varscan2
- ZFP30 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 36/81 reads (44%) | catalogued as COSV100665810; called by muse, mutect2, varscan2
- ZNF134 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 42/196 reads (21%) | catalogued as COSV101270700; called by muse, mutect2, varscan2
- ZNF835 | c.1004C>A p.A335E | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as COSV101606268, COSV73379314; called by muse, mutect2, varscan2
- ZRANB3 | c.1368G>A p.W456* | Nonsense Mutation (SNP) | VAF 39/209 reads (19%) | catalogued as COSV99922700; called by muse, mutect2, varscan2
- AJAP1 | c.1201T>G p.F401V | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2
- ARID1A | c.2172_2193del p.M724Ifs*11 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.3609_3623del p.E1203_P1207del | In Frame Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel
- PRDM15 | c.2622del p.K875Rfs*32 | Frame Shift Del (DEL) | VAF 28/121 reads (23%) | called by mutect2, pindel, varscan2
- RBP3 | c.1939C>A p.L647M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ANKRD11 | c.5511G>T p.P1837= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as rs760829206, COSV99968408; called by muse, mutect2, varscan2
- CARMIL2 | c.1224C>T p.P408= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100575963; called by muse, mutect2, varscan2
- FBXL7 | c.1374G>A p.T458= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100309131; called by muse, mutect2, varscan2
- GOT1L1 | c.558T>A p.I186= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV100294333; called by muse, mutect2, varscan2
- GRIN2A | c.1848C>T p.S616= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs372324916; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHV3-66 | c.264C>T p.I88= | Silent (SNP) | VAF 56/251 reads (22%) | called by muse, mutect2, varscan2
- KY | c.777G>A p.Q259= | Silent (SNP) | VAF 41/85 reads (48%) | catalogued as COSV101414946, COSV71017698; called by muse, mutect2, varscan2
- LCE2D | c.309C>T p.C103= | Silent (SNP) | VAF 54/164 reads (33%) | catalogued as rs1221813311, COSV64229312; called by muse, mutect2, varscan2
- LRRC6 | c.343C>T p.L115= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV51548086; called by muse, mutect2, varscan2
- NCOA6 | c.1191C>T p.G397= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV100749917; called by muse, mutect2, varscan2
- OR5A1 | c.372C>T p.D124= | Silent (SNP) | VAF 80/284 reads (28%) | catalogued as COSV100118271; called by muse, mutect2, varscan2
- PAGE3 | c.243G>T p.G81= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs1256195453, COSV100891971; called by muse, mutect2, varscan2
- PRODH2 | c.156G>T p.L52= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs746700445, COSV99995169; called by muse, mutect2, varscan2
- RIPOR1 | c.756G>A p.V252= (on ENST00000379312 / NM_001193522.2; = p.V248= on NM_024519.4) | Silent (SNP) | VAF 132/267 reads (49%) | catalogued as COSV99242588; called by muse, mutect2, varscan2
- SLC17A2 | c.291C>A p.S97= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99613934; called by muse, mutect2, varscan2
- SLC26A2 | c.1314A>T p.A438= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99639998; called by muse, mutect2, varscan2
- SYNGAP1 | c.1695G>C p.L565= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99537880; called by muse, varscan2
- ACBD4 | chr17:45143456 G>A | 3'Flank (SNP) | VAF 18/50 reads (36%) | catalogued as rs1266943544, COSV100203395; called by muse, mutect2, varscan2
- SFTA3 | n.795A>G | RNA (SNP) | VAF 4/8 reads (50%) | catalogued as rs377270948; called by muse, mutect2, varscan2
- TBX1 | c.1009+709C>T | Intron (SNP) | VAF 6/63 reads (10%) | catalogued as rs1220689917, COSV100226377; called by muse, mutect2
